Gene-level copy-number profile of tumor specimen TCGA-F5-6864-01A from TCGA case TCGA-F5-6864, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 74.1 years (27,058 days).
Specimen TCGA-F5-6864-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.c7d4279b-c302-4ea6-9f76-0d6300bc23ac.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F5-6864-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b93b96c6-9996-4493-a9e1-5d67414e704a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 2: 7,710; copy number 3: 2,145; copy number 4: 37,331; copy number 5: 4,972; copy number 6: 4,159; copy number 7: 139; copy number 8: 662; copy number 9: 1,592; copy number 10: 847; copy number 12: 256.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F5-6864-01A-11D-1923-01): tumor purity 0.48, ploidy 4.36, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,695 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:42,416,475–145,066,685, 1,577 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr13:80,697,177–81,302,407, 8 genes, copy number 9 (within-gene range 4–9): AL590807.1, ARF4P4, LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2.
- chr13:83,877,205–84,448,603, 7 genes, copy number 9: SLITRK1, AL355481.1, VENTXP2, AL590681.1, UBE2D3P4, AL445604.1, AL162493.1.
- chr20:17,941,597–18,766,644, 35 genes, copy number 10 (within-gene range 2–10): SNX5, OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, AL049646.2, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1, SEC23B, SMIM26, AL121900.1, DTD1, RN7SL638P, RNU6ATAC34P, DUXAP7.
- chr20:20,659,710–64,313,132, 1,068 genes, copy number 10–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
